Surgical pathology report (de-identified scan), TCGA case TCGA-24-1422, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1422-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT
FINAL

Patient Name

Address:

Gender:

DOB:

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned: s

Reported:

Physician(s):

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- PARAOVARIAN SEROUS CYSTADENOMA
- SEROUS ADENOCARCINOMA, HIGH GRADE (SEE COMMENT)
- STROMA LUTEINIZATION

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA, HIGH GRADE, INVOLVING SEROSAL SURFACE

OVARY, LEFT SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA, HIGH GRADE
- STROMAL LUTEINIZATION

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA, HIGH GRADE, INVOLVING SEROSAL SURFACE

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- FOLLICULAR CERVICITIS

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- CYSTIC ATROPHY

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- LEIOMYOMATA, LARGEST 1 CM GREATEST DIMENSION

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- SEROUS ADENOCARCINOMA, HIGH GRADE

OMENTUM, OMENTECTOMY

- SEROUS ADENOCARCINOMA, HIGH GRADE (SEE COMMENT)

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Brought to frozen area is a 'right tube and ovary,' consisting of a multicystic ovary measuring 7.3 x 4.7 x 4.5 cm and a fallopian tube measuring 6.3 cm in length and 0.7 cm in diameter, weighing 85 grams total. The serosal surface of both ovary and fallopian tube are studded with nodules, ranging from 0.1 x 0.1 x 0.1 cm to 0.5 x 0.3 x 0.2 cm. On the surface of the ovary is a 0.6 x 0.4 x 0.3 cm nodule, somewhat different in character. Sections show a firm and tan-white cut surface. The outer surface is inked black. The ovary is sectioned to reveal multiple cysts with smooth inner linings and trabeculations, measuring up to 4.0 x 2.5 x 2.5 cm. A section was taken of a serosal nodule, and frozen as 'FS1.' Rest for permanents,"

FS1: Ovary and fallopian tube, right salpingo-oophorectomy

Microscopic Description and Comment:

Histologic sections from the right ovary show a large cyst that appears to be paraovarian. It is lined by benign ciliated epithelium is most consistent with a benign serous cyst adenoma. On the surface of this cyst, however, are small nodules of metastatic high grade serous adenocarcinoma. The bulk of the malignant tumor in this case is located in the omentum with small implants on both fallopian tubes, left ovary, and on the serosal surface of the uterus. These findings are most consistent with a primary peritoneal carcinoma.

History:

with ascites and a pelvic mass. Operative procedure: Examination under anesthesia, exploratory laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, infracolic omentectomy, and optimal tumor debulking.

Specimen(s) Received:

A: RIGHT TUBE AND OVARY
B: UTERUS, CERVIX, LEFT TUBE AND OVARY
C: OMENTUM

Gross Description:

The specimens are received in three formalin-filled containers, each labeled "right tube and ovary." The first container is labeled "right tube and ovary." It contains a tissue cassette labeled "FS1" that holds a 2.5 x 1.5 x 0.3 cm piece of yellow-tan tissue. Also in the container is a previously inked and sectioned right adnexa, consisting of a 7.3 x 4.7 x 4.5 cm multicystic ovary, and a 6.3 x 0.7 cm fallopian tube. There is a 0.6 x 0.4 x 0.4 cm white-tan, firm nodule on the surface of the ovary. In addition, the serosal surface of the ovary and fallopian tube are studded with nodules ranging from 0.1 x 0.1 cm to 0.5 x 0.3 cm, as described in the intraoperative non-microscopic consultation. The ovary is sectioned to show a 4 x 2.5 x 2.5 cm multiloculated cystic mass with a white-tan, smooth inner lining. There are no solid areas within the cystic mass. The uninvolved ovary is sectioned to show yellow-tan, unremarkable ovarian parenchyma. The fallopian tube is sectioned to show white-tan mucosa with a patent lumen. Labeled A2 to A7 - ovary with cystic mass (A4 - serosal nodule); A8 - fallopian tube.

The second container is labeled "uterus, cervix, left tube and ovary." It contains a 43 gram uterus with attached cervix. The uterus measures 7 cm from superior to inferior, 4 cm from cornu to cornu, and 3 cm from anterior to posterior. The serosal surface of the uterus shows fibrous adhesions anteriorly. However, it is smooth and shiny posteriorly. The 2 x 2 cm tan ectocervix has multiple areas of red-brown pinpoint hemorrhages with a 0.6 cm external os. The 1.7 cm long endocervical canal is lined by pink-tan mucosa and has scattered Nabothian cysts, the largest measuring 0.4 cm. The

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

3.5 x 1.2 cm endometrial cavity is pink-tan and unremarkable. The endometrium is 0.2 cm thick; the myometrium is 0.8 cm thick. The myometrium contains three well circumscribed, tan-white, firm lesions with whorled cut surfaces, free of hemorrhage and necrosis, measuring 1 cm, 0.6 cm, and 0.5 cm in greatest dimension, consistent with leiomyomas. The largest leiomyoma shows focal calcification. There is also a 0.5 x 0.3 cm subserosal leiomyoma anteriorly. Also in the container is a detached, 10 gram left adnexa including a 2.5 x 2.2 x 1 cm ovary and a 4 x 0.6 cm attached fallopian tube. The surface of the ovary and fallopian tube shows extensive fibrous adhesions. There are multiple paratubal cysts, the largest measuring 1.2 cm in greatest dimension. The ovary is sectioned to show yellow-tan unremarkable ovarian parenchyma. The fallopian tube is sectioned to show white-tan mucosa with a patent lumen. There are no discrete lesions. Labeled B1 and B2 - anterior and posterior ectocervix; B3 and B4 - anterior and posterior lower uterine segment; B5 and B6 - anterior and posterior endomyometrium; B7 - leiomyoma; B8 - left ovary; B9 - left ovary with paratubal cyst; B10 - left fallopian tube. Jar 1.

The third container is labeled "omentum." It contains an 18 x 10 x 1.5 cm piece of yellow-tan fibroadipose tissue. Sectioned to show multiple white-tan, firm tumor implants, the largest measuring 2.5 cm in greatest dimension. Labeled C1 and C2.

Source: NCI Genomic Data Commons file c45a6d95-7dfc-4ca8-846e-f7d56288be23 (TCGA-24-1422.8BCB6CF4-84EA-41A1-9113-061A7523C19F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).